Somatic mutation profile of cancer-model specimen HCM-SANG-0287-C20-85A (3D Organoid; aliquot HCM-SANG-0287-C20-85A-01D-A78U-36), derived from the primary tumor of HCMI case HCM-SANG-0287-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0287-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ce5815d-bc0a-433e-8dd2-bc5154769544.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0287-C20-10A (Blood Derived Normal), aliquot HCM-SANG-0287-C20-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9b8327b-3bca-4abb-9957-c4bf50a53e19

The open-access MAF lists 205 somatic variants for this specimen: 147 protein-altering or splice-affecting, 46 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 46, Nonsense Mutation 8, Intron 7, Frame Shift Del 7, Frame Shift Ins 7, In Frame Del 6, Splice Region 4, Splice Site 2, 3'UTR 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 137/292 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 286/287 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCYAP1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.306); catalogued as rs748742011, COSV99327603; called by muse, mutect2, varscan2
- ADH1C | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs1395450124; called by muse, mutect2, varscan2
- AL592490.1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV101308184; called by muse, mutect2, varscan2
- APLP2 | c.2249A>G p.Y750C | Missense Mutation (SNP) | VAF 126/451 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs948881705; called by muse, mutect2, varscan2
- BCL9L | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 66/214 reads (31%) | catalogued as COSV52689388; called by muse, mutect2, varscan2
- C10orf71 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 189/393 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs370360133, COSV60511909; called by muse, mutect2, varscan2
- CALM2 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as COSV55399449; called by muse, varscan2
- CDHR5 | c.817C>G p.P273A | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1283342900; called by muse, mutect2, varscan2
- CIB2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 201/278 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs756137635, COSV51948720; called by muse, mutect2, varscan2
- COL6A2 | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 116/378 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs376368468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.9983C>T p.S3328L (on ENST00000520002; = p.S3327L on NM_033225.6) | Missense Mutation (SNP) | VAF 106/128 reads (83%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as rs893531999, COSV59369885; called by muse, mutect2, varscan2
- CSMD1 | c.4608C>A p.N1536K (on ENST00000520002; = p.N1535K on NM_033225.6) | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59307915; called by muse, mutect2, varscan2
- CSMD3 | c.3629C>T p.S1210L (on ENST00000297405 / NM_001363185.1; = p.S1106L on NM_052900.3) | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs749839773, COSV52105227; called by muse, mutect2, varscan2
- DIP2C | c.4408G>C p.V1470L | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55167546; called by muse, mutect2, varscan2
- DNAH3 | c.2429G>A p.R810H | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as rs1189581952, COSV54542910; called by muse, mutect2, varscan2
- EFR3A | c.1855C>A p.Q619K | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs769570399; called by muse, mutect2, varscan2
- EPHB3 | c.31_42del p.S11_P14del | In Frame Del (DEL) | VAF 104/128 reads (81%) | catalogued as rs1337298955; called by mutect2, varscan2
- FAM135B | c.2173C>T p.R725W | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs537059837; called by muse, mutect2, varscan2
- FBN2 | c.7396A>T p.I2466F | Missense Mutation (SNP) | VAF 170/327 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as CM148694; called by muse, mutect2, varscan2
- FBXO40 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 255/256 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs144524810; called by muse, mutect2, varscan2
- FRY | c.5064dup p.L1689Tfs*30 | Frame Shift Ins (INS) | VAF 132/490 reads (27%) | catalogued as rs1566147362; called by mutect2, pindel, varscan2
- FZD1 | c.1363C>A p.P455T | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55311217; called by muse, mutect2, varscan2
- GOLGB1 | c.3193A>G p.T1065A | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100511417; called by muse, mutect2, varscan2
- GUCA1B | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146279104; called by muse, mutect2, varscan2
- IBA57 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs767607200; called by muse, mutect2
- IFI44L | c.521C>G p.A174G | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.783); catalogued as rs1197500439; called by muse, mutect2, varscan2
- IGF2BP3 | c.898A>T p.K300* | Nonsense Mutation (SNP) | VAF 57/214 reads (27%) | catalogued as rs1371233673, COSV51681276, COSV51682646; called by muse, mutect2, varscan2
- IGSF10 | c.7228C>T p.R2410C | Missense Mutation (SNP) | VAF 232/232 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs771354299; called by muse, mutect2, varscan2
- JPH2 | c.1235C>G p.S412C | Missense Mutation (SNP) | VAF 238/1384 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.98); catalogued as rs1004964815; called by muse, mutect2, varscan2
- KIAA0408 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV64108727; called by muse, mutect2, varscan2
- KMT2A | c.7322A>T p.H2441L | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV100628844; called by muse, mutect2, varscan2
- MARCHF4 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.709); catalogued as rs765369049; called by muse, mutect2, varscan2
- MMP9 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 491/930 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs776529410, COSV63433955; called by muse, mutect2, varscan2
- NEB | c.1816G>T p.G606W | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50806770; called by muse, mutect2, varscan2
- NME8 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 60/290 reads (21%) | catalogued as COSV52247226; called by muse, mutect2, varscan2
- NPAS4 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV60649858; called by muse, mutect2, varscan2
- OSBPL6 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51926497; called by muse, mutect2, varscan2
- P2RY12 | c.772C>G p.P258A | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM073249, COSV99851387; called by muse, mutect2, varscan2
- PARP3 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs757453925; called by muse, mutect2, varscan2
- PCSK6 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 141/197 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs776046303; called by muse, mutect2, varscan2
- PKD1L2 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 239/788 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753472684, COSV55170924; called by muse, mutect2, varscan2
- PTPRN2 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 89/306 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369875860, COSV101235371; called by muse, mutect2, varscan2
- PTPRS | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.616); catalogued as rs761681941, COSV53626170; called by muse, mutect2, varscan2
- PTPRT | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 182/939 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs754008236, COSV61995672; called by muse, mutect2, varscan2
- RAB6B | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV53314281; called by muse, mutect2, varscan2
- RGS9 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 206/409 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs761061220, COSV52224279; called by muse, mutect2, varscan2
- SACS | c.10651A>T p.M3551L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs770752326; called by muse, mutect2, varscan2
- SLC27A6 | c.354C>G p.F118L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV52479372; called by muse, mutect2, varscan2
- SLC5A5 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 335/535 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs140356148; called by muse, mutect2
- SLIT3 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 174/175 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs542537536, COSV60618590; called by muse, mutect2, varscan2
- SPAG6 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs751414200, COSV57617831; called by muse, mutect2, varscan2
- SS18L1 | c.1174G>C p.G392R | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59210168; called by muse, mutect2, varscan2
- TBCB | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1168290471; called by muse, mutect2, varscan2
- TFPI2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs759459076, COSV55990365; called by muse, mutect2, varscan2
- THBS1 | c.2380G>A p.G794R | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764179721; called by muse, mutect2, varscan2
- TMEM134 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 147/462 reads (32%) | catalogued as rs756229958; called by muse, mutect2, varscan2
- TTC17 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs749725093, COSV50005967; called by muse, mutect2, varscan2
- TTN | c.47885G>T p.G15962V (on ENST00000591111; = p.G8538V on NM_003319.4) | Missense Mutation (SNP) | VAF 171/594 reads (29%) | PolyPhen probably damaging (1); catalogued as COSV100592029; called by muse, mutect2, varscan2
- TUBA3E | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 107/414 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as rs1224530569; called by muse, mutect2, varscan2
- URI1 | c.758C>G p.T253R | Missense Mutation (SNP) | VAF 129/206 reads (63%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.467); catalogued as rs1475597277; called by muse, mutect2, varscan2
- VARS2 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 69/69 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140305500; called by muse, mutect2, varscan2
- ZNF91 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV56081243; called by muse, mutect2, varscan2
- ADAMTS4 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AGBL1 | c.2534C>A p.P845Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ANKRD36 | c.2732dup p.D912Gfs*6 | Frame Shift Ins (INS) | VAF 73/267 reads (27%) | called by mutect2, varscan2
- AOX1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ARFGEF2 | c.977C>G p.A326G | Missense Mutation (SNP) | VAF 215/1287 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD9 | c.214_228del p.K72_K76del | In Frame Del (DEL) | VAF 105/424 reads (25%) | called by mutect2, pindel, varscan2
- CASP8 | c.1068dup p.I357Yfs*8 (on ENST00000432109 / NM_033355.3; = p.I374Yfs*8 on NM_001228.4) | Frame Shift Ins (INS) | VAF 150/546 reads (27%) | called by mutect2, pindel, varscan2
- CBARP | c.626_627del p.A209Efs*40 (on ENST00000382477; = p.A189Efs*40 on NM_152769.3) | Frame Shift Del (DEL) | VAF 92/371 reads (25%) | called by mutect2, pindel, varscan2
- CCDC160 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 191/191 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCDC168 | c.10686_10707del p.Q3562Hfs*31 | Frame Shift Del (DEL) | VAF 18/198 reads (9%) | called by mutect2, pindel
- CCN3 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 148/359 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- CDH18 | c.2144T>G p.F715C | Missense Mutation (SNP) | VAF 195/311 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CHD6 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 408/990 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIT | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 79/239 reads (33%) | called by muse, mutect2, varscan2
- CMAHP | n.1099G>C | Splice Region (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- CNTLN | c.927G>C p.Q309H | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CYP11B2 | c.346T>G p.W116G | Missense Mutation (SNP) | VAF 91/580 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCHS2 | c.386_391del p.R129_R130del | In Frame Del (DEL) | VAF 97/248 reads (39%) | called by mutect2, pindel, varscan2
- DNAH11 | c.125A>C p.E42A | Missense Mutation (SNP) | VAF 148/480 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELF3 | c.900dup p.G301Rfs*170 | Frame Shift Ins (INS) | VAF 141/284 reads (50%) | called by mutect2, pindel, varscan2
- ESRRG | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYA1 | c.1754_1758del p.H585Lfs*45 | Frame Shift Del (DEL) | VAF 60/529 reads (11%) | called by mutect2, pindel, varscan2
- FAM117B | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 184/621 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FAM135B | c.843A>C p.E281D | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FARP2 | c.367_368insG p.F123Cfs*5 | Frame Shift Ins (INS) | VAF 67/244 reads (27%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1489T>G p.L497V (on ENST00000281708 / NM_001349798.2; = p.L417V on NM_018315.5) | Missense Mutation (SNP) | VAF 151/292 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- FLRT2 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- FLT1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 151/238 reads (63%) | called by muse, mutect2, varscan2
- GATA3 | c.840del p.H281Tfs*13 | Frame Shift Del (DEL) | VAF 162/582 reads (28%) | called by mutect2, pindel, varscan2
- GET4 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLRA4 | c.532A>G p.N178D | Missense Mutation (SNP) | VAF 183/316 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- GPR158 | c.224C>G p.A75G | Missense Mutation (SNP) | VAF 123/740 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HECTD1 | c.3375A>C p.L1125F | Missense Mutation (SNP) | VAF 104/513 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HECTD2 | c.1757T>A p.V586D | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HS3ST1 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IGFN1 | c.1997_1998del p.R666Pfs*34 (on ENST00000295591 / NM_001367841.1; = p.R3123Pfs*34 on NM_001164586.2) | Frame Shift Del (DEL) | VAF 70/244 reads (29%) | called by mutect2, pindel, varscan2
- IL1R2 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IL1RAP | c.1048A>C p.K350Q | Missense Mutation (SNP) | VAF 72/72 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- INTS10 | c.1976A>C p.K659T | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KCNB1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 249/561 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNC2 | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 115/403 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1109 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LAPTM4B | c.592_594del p.Y198del (on ENST00000445593; = p.Y107del on NM_018407.6) | In Frame Del (DEL) | VAF 39/113 reads (35%) | called by mutect2, pindel, varscan2
- LINC02740 | n.333_334del | Splice Region (DEL) | VAF 81/255 reads (32%) | called by mutect2, pindel, varscan2
- LIPA | c.912G>C p.K304N | Missense Mutation (SNP) | VAF 155/344 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LONRF2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- LRBA | c.7297C>G p.Q2433E | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LRRN3 | c.806_807delinsT p.K269Ifs*18 | Frame Shift Del (DEL) | VAF 43/171 reads (25%) | called by pindel, varscan2*
- METTL21C | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 111/188 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLANA | c.177T>C p.D59= | Splice Region (SNP) | VAF 94/95 reads (99%) | called by muse, mutect2, varscan2
- MUC16 | c.11630C>T p.P3877L | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 119/358 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYLIP | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 165/585 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NCAM1 | c.1701G>A p.M567I (on ENST00000316851 / NM_181351.5; = p.M557I on NM_000615.7) | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFATC2 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- NNT | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPAS3 | c.2209G>A p.A737T (on ENST00000356141 / NM_001164749.2; = p.A705T on NM_022123.3) | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR1E2 | c.937del p.V313Sfs*? | Frame Shift Del (DEL) | VAF 50/140 reads (36%) | called by mutect2, pindel
- OR1L6 | c.641T>G p.F214C (on ENST00000373684; = p.F178C on NM_001004453.2) | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T10 | c.472_498del p.M158_F166del | In Frame Del (DEL) | VAF 150/830 reads (18%) | called by mutect2, pindel
- OR5A1 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 106/364 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PABPC3 | c.752T>A p.M251K | Missense Mutation (SNP) | VAF 212/327 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PCDHGA5 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 235/472 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PIK3R6 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POLB | c.120_124del p.X40_splice | Splice Site (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- PPIG | c.1316G>C p.R439T | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PTGFR | c.437A>T p.K146I | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- RDH14 | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 97/330 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCFD1 | c.1242+3A>C | Splice Region (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- SNRPC | c.228G>C p.M76I | Missense Mutation (SNP) | VAF 104/368 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STOML2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 144/467 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SULT2B1 | c.848dup p.N283Kfs*29 (on ENST00000201586 / NM_177973.2; = p.N268Kfs*29 on NM_004605.2) | Frame Shift Ins (INS) | VAF 145/484 reads (30%) | called by mutect2, pindel, varscan2
- TAF3 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 38/434 reads (9%) | called by muse, mutect2
- TAS2R30 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 126/391 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TCHH | c.5403_5414del p.Q1802_Q1805del | In Frame Del (DEL) | VAF 109/540 reads (20%) | called by mutect2, pindel, varscan2
- TEX15 | c.7438T>G p.F2480V (on ENST00000256246; = p.F2863V on NM_001350162.2) | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TM9SF4 | c.660dup p.A221Sfs*3 | Frame Shift Ins (INS) | VAF 95/471 reads (20%) | called by mutect2, pindel, varscan2
- TRIM46 | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 117/417 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TTN | c.80506G>T p.E26836* (on ENST00000591111; = p.E19412* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 73/276 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.61279A>G p.T20427A (on ENST00000591111; = p.T13003A on NM_003319.4) | Missense Mutation (SNP) | VAF 128/424 reads (30%) | PolyPhen benign (0.107); called by muse, varscan2
- USP15 | c.2928C>G p.N976K (on ENST00000280377 / NM_001351159.2; = p.N947K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); called by muse, varscan2
- VSX1 | c.628-9_643del p.X210_splice | Splice Site (DEL) | VAF 73/289 reads (25%) | called by mutect2, pindel, varscan2
- ZNF292 | c.7850C>G p.T2617S | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP1 | c.1680G>A p.E560= | Silent (SNP) | VAF 121/263 reads (46%) | called by muse, mutect2, varscan2
- CCDC168 | c.14199T>G p.P4733= | Silent (SNP) | VAF 184/283 reads (65%) | catalogued as rs1404163576; called by muse, mutect2, varscan2
- DAB2IP | c.1527C>T p.R509= (on ENST00000408936; = p.R481= on NM_032552.3) | Silent (SNP) | VAF 180/381 reads (47%) | called by muse, mutect2, varscan2
- DCSTAMP | c.51T>A p.I17= | Silent (SNP) | VAF 42/230 reads (18%) | called by muse, mutect2, varscan2
- DHX35 | c.726A>G p.T242= | Silent (SNP) | VAF 166/482 reads (34%) | called by muse, mutect2, varscan2
- DOCK10 | c.5334A>T p.P1778= | Silent (SNP) | VAF 62/210 reads (30%) | called by muse, mutect2, varscan2
- DPP6 | c.1446C>T p.S482= (on ENST00000377770 / NM_001364500.2; = p.S420= on NM_001936.5) | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as rs753202667, COSV100126232, COSV59599271; called by muse, mutect2, varscan2
- EFCAB6 | c.2427A>G p.R809= | Silent (SNP) | VAF 94/94 reads (100%) | called by muse, mutect2, varscan2
- EHMT1 | c.3417C>T p.G1139= | Silent (SNP) | VAF 413/415 reads (100%) | catalogued as rs747339529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF3H | c.579C>T p.T193= | Silent (SNP) | VAF 77/204 reads (38%) | catalogued as rs763423573; called by muse, mutect2, varscan2
- ELOA2 | c.1638C>T p.D546= | Silent (SNP) | VAF 246/507 reads (49%) | catalogued as rs754698908; called by muse, mutect2, varscan2
- EPHX2 | c.282G>A p.K94= | Silent (SNP) | VAF 69/229 reads (30%) | called by muse, mutect2, varscan2
- EPPK1 | c.4542G>A p.R1514= | Silent (SNP) | VAF 60/333 reads (18%) | called by muse, mutect2, varscan2
- ERMARD | c.633G>A p.T211= | Silent (SNP) | VAF 61/179 reads (34%) | catalogued as rs754240113; called by muse, mutect2, varscan2
- FAM184A | c.2295G>A p.E765= | Silent (SNP) | VAF 64/176 reads (36%) | catalogued as rs1309629339; called by mutect2, varscan2
- FAM187B | c.669C>G p.L223= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as rs747872397, COSV61201543; called by muse, mutect2, varscan2
- FAM71A | c.144C>T p.S48= | Silent (SNP) | VAF 51/285 reads (18%) | catalogued as rs141841205; called by muse, mutect2, varscan2
- FPR1 | c.951C>G p.P317= | Silent (SNP) | VAF 181/602 reads (30%) | catalogued as COSV59051130; called by muse, mutect2, varscan2
- HMCN1 | c.1944C>T p.N648= | Silent (SNP) | VAF 183/275 reads (67%) | catalogued as rs762283413, COSV54940527; called by muse, mutect2, varscan2
- IGKV6-21 | c.312G>A p.T104= | Silent (SNP) | VAF 176/274 reads (64%) | catalogued as rs201999187; called by muse, mutect2, varscan2
- JHY | c.1056G>C p.V352= | Silent (SNP) | VAF 95/270 reads (35%) | called by muse, mutect2, varscan2
- LATS2 | c.2835G>A p.R945= | Silent (SNP) | VAF 67/107 reads (63%) | called by muse, mutect2, varscan2
- NDUFA6 | c.102G>A p.E34= | Silent (SNP) | VAF 249/551 reads (45%) | called by muse, mutect2, varscan2
- NRDE2 | c.2691C>T p.T897= | Silent (SNP) | VAF 82/198 reads (41%) | catalogued as rs373558788; called by muse, mutect2, varscan2
- OR10H2 | c.141C>T p.A47= | Silent (SNP) | VAF 66/243 reads (27%) | called by muse, mutect2, varscan2
- OR7D4 | c.834C>T p.Y278= | Silent (SNP) | VAF 91/337 reads (27%) | catalogued as rs771972062, COSV58071421; called by muse, mutect2, varscan2
- PCDHB3 | c.2037C>A p.A679= | Silent (SNP) | VAF 255/496 reads (51%) | catalogued as COSV99166567; called by muse, mutect2, varscan2
- PCDHB6 | c.1341C>T p.P447= | Silent (SNP) | VAF 295/634 reads (47%) | catalogued as COSV50700539; called by muse, mutect2, varscan2
- PDZD2 | c.4671T>C p.D1557= | Silent (SNP) | VAF 161/464 reads (35%) | called by muse, mutect2, varscan2
- PIDD1 | c.1290A>G p.E430= | Silent (SNP) | VAF 116/362 reads (32%) | catalogued as rs1180469485; called by muse, mutect2, varscan2
- PPFIA2 | c.2505A>G p.G835= | Silent (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- PRPF39 | c.417A>G p.E139= | Silent (SNP) | VAF 56/152 reads (37%) | called by muse, mutect2, varscan2
- RASA4 | c.393G>T p.R131= | Silent (SNP) | VAF 17/165 reads (10%) | called by mutect2, varscan2
- RASA4B | c.393G>T p.R131= | Silent (SNP) | VAF 113/816 reads (14%) | called by muse, mutect2, varscan2
- RGPD4 | c.30G>T p.R10= | Silent (SNP) | VAF 199/621 reads (32%) | catalogued as COSV61749735; called by muse, mutect2, varscan2
- ROBO2 | c.1785C>T p.V595= | Silent (SNP) | VAF 158/334 reads (47%) | catalogued as rs960884394; called by muse, mutect2, varscan2
- SAMD9L | c.4734A>T p.A1578= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1562785619; called by muse, mutect2
- SF3B3 | c.1791T>G p.P597= | Silent (SNP) | VAF 131/442 reads (30%) | called by muse, mutect2, varscan2
- SLITRK2 | c.2217C>T p.A739= | Silent (SNP) | VAF 127/238 reads (53%) | called by muse, mutect2, varscan2
- SPIC | c.135T>G p.P45= | Silent (SNP) | VAF 68/254 reads (27%) | catalogued as COSV100162852; called by muse, mutect2, varscan2
- SSUH2 | c.87G>A p.P29= | Silent (SNP) | VAF 160/321 reads (50%) | catalogued as rs370665019; called by muse, mutect2, varscan2
- TAF3 | c.2364G>T p.S788= | Silent (SNP) | VAF 38/433 reads (9%) | catalogued as COSV100720605; called by muse, mutect2
- TMEM178B | c.672C>T p.A224= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs1320143136; called by muse, mutect2, varscan2
- UTRN | c.2607T>A p.P869= | Silent (SNP) | VAF 100/295 reads (34%) | called by muse, mutect2, varscan2
- YBX2 | c.903G>A p.E301= | Silent (SNP) | VAF 131/327 reads (40%) | called by muse, mutect2, varscan2
- ZNF200 | c.312G>C p.V104= | Silent (SNP) | VAF 55/203 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.825-110C>G | Intron (SNP) | VAF 157/323 reads (49%) | called by muse, mutect2, varscan2
- DENND1B | c.83-20590C>T | Intron (SNP) | VAF 218/598 reads (36%) | catalogued as rs894253535; called by muse, mutect2, varscan2
- FAM136A | c.87+288A>T | Intron (SNP) | VAF 112/345 reads (32%) | called by muse, mutect2, varscan2
- GNAS | chr20:58889183 C>T | 5'Flank (SNP) | VAF 81/472 reads (17%) | called by muse, mutect2, varscan2
- GPI | c.123-353C>T | Intron (SNP) | VAF 139/474 reads (29%) | catalogued as rs767777763; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901008 T>C | 3'Flank (SNP) | VAF 223/1392 reads (16%) | called by muse, mutect2, varscan2
- PKP3 | c.-18C>T | 5'UTR (SNP) | VAF 161/527 reads (31%) | called by muse, mutect2, varscan2
- QRICH2 | c.207+2944C>G | Intron (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- TCF4 | c.72+42dup | Intron (INS) | VAF 80/164 reads (49%) | catalogued as rs750111635; called by mutect2, varscan2
- TMEM135 | c.*2399C>T | 3'UTR (SNP) | VAF 53/143 reads (37%) | catalogued as rs896441672; called by muse, mutect2, varscan2
- TTN | c.10361-4086C>A | Intron (SNP) | VAF 55/148 reads (37%) | catalogued as COSV60331835, COSV60369370; called by muse, mutect2, varscan2
- UQCRB | c.*1845G>A | 3'UTR (SNP) | VAF 100/309 reads (32%) | called by muse, mutect2, varscan2
